TCGA case TCGA-DD-A1EJ — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/52292ffc-0902-4d97-b461-20723987a177

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 71 years; Vital status: Dead; Days to death: 1,005 days (2.8 years).

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 71.2 years (26,009 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Child pugh classification: B; Ishak fibrosis score: 0 - No Fibrosis.
   Pathology details: Additional pathology findings: Inflammation; Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Sorafenib; Days to treatment start: 264 days; Days to treatment end: 887 days (2.4 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radioembolization; Days to treatment start: 277 days; Embolic agent: Y-90 Therasphere.
   Treatment given: Treatment type: Radioembolization; Days to treatment start: 300 days; Embolic agent: Y-90 Therasphere.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin + Mitomycin; Days to treatment start: 424 days (1.2 years).
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin + Mitomycin; Days to treatment start: 495 days (1.4 years).
   Treatment given: Treatment type: Chemoembolization; Days to treatment start: 760 days (2.1 years).
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 71.9 years (26,272 days); Days to diagnosis: 263 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 263 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Liver; Days to recurrence: 263 days.
- Days to follow up: 887 days (2.4 years); Disease response: With Tumor.
- Days to follow up: 1,005 days (2.8 years); Disease response: With Tumor.
- ECOG performance status: 2.

Molecular and laboratory tests
- Platelets 608 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 450].
- Alpha Fetoprotein 18840 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 6].
- Total Bilirubin 0.7 mg/dL [Blood test normal range lower: 0.1; Blood test normal range upper: 1].
- Prothrombin Time 10.2 Seconds [Blood test normal range lower: 8.3; Blood test normal range upper: 10.8].
- Albumin 3.5 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.2; Blood test normal range upper: 5].
- Creatinine 0.6 mg/dL [Blood test normal range lower: 0.6; Blood test normal range upper: 1.1].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Viral hepatitis serology tests: Hepatitis B Surface Antigen / HBV Surface Antibody / HBV Core Antibody.
- Timepoint category: Initial Diagnosis; Weight: 64 kg; Height: 154 cm; BMI: 27.

Family history
- Relatives with cancer history count: 1.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DD-A1EJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 290 mg.
  Slide TCGA-DD-A1EJ-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DD-A1EJ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DD-A1EJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-DD-A1EJ-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 130 mg.
  Slide TCGA-DD-A1EJ-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 85; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Lobectomy; Hepatic inflammation adj tissue: Mild.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis B Surface Antigen; Viral hepatitis serology: HBV Surface Antibody; Viral hepatitis serology: HBV Core Antibody.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment: Treatment best response: Clinical Progressive Disease.
- Ablations, Ablation, Ablation treatments: Ablation performed indicator: No.
- Ablations, Ablation, Embolization treatments: Embolization performed indicator: Yes.
- Ablations, Ablation, Embolization treatments, Embolization treatment 3: Embolization therapy drug name: Doxorubicin/mitomycin.
- Ablations, Ablation, Embolization treatments, Embolization treatment 5: Embolization therapy drug name: chemoembolic mixture.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,005 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,005 days; disease-free interval: event (new tumor event after initially disease-free), 263 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 263 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DD-A1EJ-01A-11D-A151-01): tumor purity 0.75, ploidy 2.31, whole-genome doublings 0.
